Somatic mutation profile of tumor specimen MMRF_2626_1_BM_CD138pos (aliquot MMRF_2626_1_BM_CD138pos_T1_KHS5U_L13298) from MMRF case MMRF_2626, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.3 years (22,760 days).
Specimen MMRF_2626_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcb0e5a5-b1d7-4754-8154-8921e1d6a360.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2626_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2626_1_PB_WBC_C3_KHS5U_L13299; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d25c0588-eb13-40ab-8321-25dab6d4511b

The open-access MAF lists 87 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 26, Missense Mutation 25, Intron 13, Silent 10, Nonsense Mutation 5, 5'UTR 2, Frame Shift Del 2, 5'Flank 1, 3'Flank 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 42/832 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CCDC185 | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs767318649; called by muse, mutect2, varscan2
- CDC42BPB | c.5030C>G p.S1677* | Nonsense Mutation (SNP) | VAF 53/92 reads (58%) | catalogued as COSV54486296; called by muse, mutect2, varscan2
- FNDC3A | c.2663A>G p.H888R (on ENST00000492622 / NM_001079673.2; = p.H832R on NM_014923.5) | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV68134902; called by muse, mutect2
- IGLV3-1 | c.214C>G p.R72G | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs61731683; called by muse, varscan2
- IRX1 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 20/523 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV57360363; called by muse, mutect2
- LAMA5 | c.3101G>A p.R1034H | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs768998301; called by muse, mutect2, varscan2
- MYO6 | c.3028C>T p.R1010W | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs148245729; called by muse, mutect2, varscan2
- PIWIL1 | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 25/88 reads (28%) | catalogued as rs369068461; called by muse, mutect2, varscan2
- PSMC5 | c.1127T>C p.V376A | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.071); catalogued as COSV56739522; called by muse, mutect2, varscan2
- RFTN1 | c.667C>G p.P223A | Missense Mutation (SNP) | VAF 99/234 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV100489789; called by muse, mutect2, varscan2
- TMEM129 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 142/170 reads (84%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as rs780884203; called by muse, mutect2, varscan2
- UNC13C | c.6409G>C p.V2137L | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99513820; called by muse, mutect2
- ABCE1 | c.1384T>G p.L462V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACTN3 | c.817del p.A273Pfs*10 | Frame Shift Del (DEL) | VAF 43/89 reads (48%) | called by mutect2, pindel*, varscan2
- APAF1 | c.2683T>C p.S895P (on ENST00000551964 / NM_181861.2; = p.S841P on NM_001160.3) | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2
- ATM | c.5468T>A p.I1823N | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- CEP350 | c.2150C>G p.S717* | Nonsense Mutation (SNP) | VAF 106/582 reads (18%) | called by muse, mutect2, varscan2
- DPP8 | c.2173A>T p.I725L (on ENST00000341861 / NM_001320875.2; = p.I709L on NM_130434.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- DTD1 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 6/127 reads (5%) | called by muse, mutect2
- MAP7 | c.2247_2248del p.I749Mfs*19 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by pindel, varscan2
- OR2J3 | c.43T>G p.F15V | Missense Mutation (SNP) | VAF 104/209 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- OTOGL | c.6467C>T p.T2156I (on ENST00000547103; = p.T2147I on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PCDH15 | c.5110A>T p.S1704C (on ENST00000644397 / NM_001354429.2; = p.S1646C on NM_001142771.2) | Missense Mutation (SNP) | VAF 109/259 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- PLEKHG5 | c.2516T>A p.L839Q (on ENST00000400915 / NM_001042663.3; = p.L802Q on NM_020631.6) | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- PMFBP1 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 11/279 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); called by muse, mutect2
- PML | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 82/134 reads (61%) | SIFT tolerated (0.14); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RNF25 | c.667-6T>C | Splice Region (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- RPRD1B | c.657C>G p.D219E | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SCAMP1 | c.302T>G p.L101* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2, varscan2
- TERF2IP | c.799T>A p.S267T | Missense Mutation (SNP) | VAF 134/337 reads (40%) | SIFT tolerated, low confidence (0.34); called by muse, mutect2, varscan2
- TRIP12 | c.5114C>T p.A1705V | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- U2AF1L4 | c.45G>T p.K15N | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ADORA2A | c.990C>T p.D330= | Silent (SNP) | VAF 123/258 reads (48%) | catalogued as rs768629854; called by muse, mutect2, varscan2
- CDIPT | c.135G>A p.L45= | Silent (SNP) | VAF 20/63 reads (32%) | called by muse, mutect2, varscan2
- KRTCAP3 | c.303G>T p.V101= | Silent (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- MYH2 | c.429C>T p.Y143= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV55443366; called by muse, mutect2
- PANK3 | c.930T>A p.V310= | Silent (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2, varscan2
- PIAS2 | c.831T>A p.I277= | Silent (SNP) | VAF 127/219 reads (58%) | called by muse, mutect2, varscan2
- PRDM6 | c.1341C>T p.N447= | Silent (SNP) | VAF 81/175 reads (46%) | catalogued as rs763073702, COSV68334951; called by muse, mutect2, varscan2
- SETD5 | c.2949G>A p.L983= | Silent (SNP) | VAF 69/208 reads (33%) | called by muse, mutect2, varscan2
- TACC2 | c.3396T>C p.T1132= | Silent (SNP) | VAF 41/81 reads (51%) | called by muse, mutect2, varscan2
- TMEM67 | c.381T>C p.C127= | Silent (SNP) | VAF 156/403 reads (39%) | called by muse, mutect2, varscan2
- AMN | c.296-40G>A | Intron (SNP) | VAF 48/67 reads (72%) | catalogued as rs780899718; called by muse, mutect2, varscan2
- ANKRD30BP1 | n.1439T>C | RNA (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- CREBRF | c.*3032T>G | 3'UTR (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- DENND11 | c.*3979G>C | 3'UTR (SNP) | VAF 48/141 reads (34%) | called by muse, mutect2, varscan2
- DLG2 | c.*3576C>T | 3'UTR (SNP) | VAF 35/69 reads (51%) | catalogued as rs761754606; called by muse, mutect2, varscan2
- DNAJC5 | c.*1792C>A | 3'UTR (SNP) | VAF 82/212 reads (39%) | called by muse, mutect2, varscan2
- DPY19L3 | c.1615-1044G>T | Intron (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- EGR3 | c.*1911T>C | 3'UTR (SNP) | VAF 28/76 reads (37%) | catalogued as rs1046495277; called by muse, mutect2, varscan2
- FANCC | c.1154+127A>G | Intron (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- GPR158 | c.*1061A>C | 3'UTR (SNP) | VAF 18/30 reads (60%) | called by muse, mutect2, varscan2
- HERC4 | c.*980A>G | 3'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- HOXA13 | c.*219C>A | 3'UTR (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- IFRD2 | c.1441-65G>A | Intron (SNP) | VAF 43/137 reads (31%) | called by muse, mutect2, varscan2
- INTS1 | c.3541+17C>T | Intron (SNP) | VAF 23/104 reads (22%) | called by muse, mutect2, varscan2
- KCTD14 | c.*861T>G | 3'UTR (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.654-41C>T | Intron (SNP) | VAF 45/104 reads (43%) | called by muse, mutect2, varscan2
- LYPLAL1 | c.361+32T>C | Intron (SNP) | VAF 5/14 reads (36%) | catalogued as rs764060452; called by muse, mutect2, varscan2
- MGAT4D | c.*867A>G | 3'UTR (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- MOB4 | c.*2392T>C | 3'UTR (SNP) | VAF 8/20 reads (40%) | catalogued as rs902074098; called by muse, mutect2, varscan2
- MTMR3 | c.557+163C>T | Intron (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- NEDD4 | c.*237A>T | 3'UTR (SNP) | VAF 16/63 reads (25%) | called by muse, mutect2, varscan2
- NEGR1 | c.*3903G>A | 3'UTR (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*9981C>T | 3'UTR (SNP) | VAF 51/96 reads (53%) | called by muse, mutect2, varscan2
- OR6F1 | chr1:247711704 G>C | 3'Flank (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- OXLD1 | c.60+153C>T | Intron (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- PDK4 | c.*1416A>C | 3'UTR (SNP) | VAF 45/77 reads (58%) | called by muse, mutect2, varscan2
- PEX5L | c.199-381G>A | Intron (SNP) | VAF 175/421 reads (42%) | called by muse, mutect2, varscan2
- RAB3IP | c.*2683A>G | 3'UTR (SNP) | VAF 37/99 reads (37%) | catalogued as rs993938359; called by muse, mutect2, varscan2
- RAD21 | c.*1399A>G | 3'UTR (SNP) | VAF 9/21 reads (43%) | called by muse, mutect2, varscan2
- RHOV | c.*647C>T | 3'UTR (SNP) | VAF 6/142 reads (4%) | catalogued as rs1257984024, COSV55028099; called by muse, mutect2
- RNF215 | c.*389A>G | 3'UTR (SNP) | VAF 90/180 reads (50%) | catalogued as rs1372624716; called by muse, mutect2, varscan2
- RNF217 | c.883-35912A>C | Intron (SNP) | VAF 11/339 reads (3%) | called by muse, mutect2
- RXRG | c.-178G>A | 5'UTR (SNP) | VAF 44/199 reads (22%) | called by muse, mutect2, varscan2
- SAMD4A | c.*3835A>G | 3'UTR (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- SERTAD2 | c.*530C>G | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- SLFNL1 | chr1:41022067 A>G | 5'Flank (SNP) | VAF 8/133 reads (6%) | called by muse, mutect2
- STS | c.*3716T>G | 3'UTR (SNP) | VAF 51/53 reads (96%) | called by muse, mutect2, varscan2
- SUZ12 | c.-211T>C | 5'UTR (SNP) | VAF 9/30 reads (30%) | catalogued as rs527723504, COSV59501564; called by muse, mutect2, varscan2
- TBXAS1 | c.333+2045A>C | Intron (SNP) | VAF 16/114 reads (14%) | called by muse, mutect2, varscan2
- TLN2 | c.*1776A>G | 3'UTR (SNP) | VAF 72/254 reads (28%) | called by muse, mutect2, varscan2
- TMEM213 | c.*2315G>A | 3'UTR (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- TMX4 | c.*584T>C | 3'UTR (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- UBE2V2 | c.17-815C>A | Intron (SNP) | VAF 6/30 reads (20%) | called by muse, varscan2
- ZFAND5 | c.*4419T>A | 3'UTR (SNP) | VAF 11/52 reads (21%) | called by muse, mutect2, varscan2
